Somatic mutation profile of tumor specimen C3L-01467-01 (aliquot CPT0390040006) from CPTAC case C3L-01467, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 70.1 years (25,602 days).
Specimen C3L-01467-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23861721-43f2-404f-a440-f3ce7df13f11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01467-31 (Blood Derived Normal), aliquot CPT0390100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/094e5f02-dda4-4d3e-aece-943313e97a27

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 4, Silent 3, 3'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQGAP3 | c.4316G>A p.R1439H | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201439773, COSV63253456; called by muse, mutect2
- NCAPH2 | c.151A>G p.M51V | Missense Mutation (SNP) | VAF 86/114 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1264620421; called by muse, mutect2, varscan2
- RBBP6 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs150507755; called by muse, mutect2, varscan2
- TLR1 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1222255510; called by muse, mutect2, varscan2
- ZNF469 | c.11684G>A p.R3895Q (on ENST00000437464; = p.R3923Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs281165935, COSV101458793; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7287A>T p.L2429F | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); called by muse, varscan2
- ATR | c.7570G>C p.G2524R | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AVIL | c.448-1G>A p.X150_splice | Splice Site (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- BSG | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CAPRIN1 | c.1936A>C p.T646P | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CSMD3 | c.5443G>T p.V1815F (on ENST00000297405 / NM_001363185.1; = p.V1711F on NM_052900.3) | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL3 | c.1595T>C p.F532S | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DAB2IP | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- LPIN1 | c.2557C>G p.L853V | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MDC1 | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 138/324 reads (43%) | called by muse, mutect2, varscan2
- NKX1-1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- SIPA1L2 | c.4463C>T p.S1488F | Missense Mutation (SNP) | VAF 99/138 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUPT6H | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- TMEM132C | c.2938C>A p.L980I | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDC34 | c.306C>T p.D102= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs1326670665, COSV99296220; called by muse, mutect2, varscan2
- KAZN | c.60C>A p.V20= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ZNF768 | c.981C>T p.A327= | Silent (SNP) | VAF 114/281 reads (41%) | called by muse, mutect2, varscan2
- ACSM2B | c.597-202A>G | Intron (SNP) | VAF 75/191 reads (39%) | called by muse, mutect2, varscan2
- BAZ1A | c.2236+43T>G | Intron (SNP) | VAF 77/106 reads (73%) | called by muse, mutect2, varscan2
- CDO1 | c.*4G>T | 3'UTR (SNP) | VAF 23/181 reads (13%) | called by muse, mutect2, varscan2
- HNRNPA3 | c.740-28T>C | Intron (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.1281-1225C>G | Intron (SNP) | VAF 55/66 reads (83%) | called by muse, mutect2, varscan2
